Surgical pathology report (de-identified scan), TCGA case TCGA-06-0165, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0165-01A (Primary Tumor).

Patient Name: 1

MRN:

Sex: Male Room/Bed:

NAME: 1

PATH.NO:

MED. REC. NO: 1

PHYSICIAN:
COPY TO:SURGERY DATE:
RECEIVE DATE:-----
PATHOLOGICAL DIAGNOSIS:A,B. LEFT FRONTAL LOBE BIOPSY: GLIOBLASTOMA MULTIFORME. (MIB-1: 30%)

Operation/Specimen:

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY:

A. 0.6 X 0.4 cm tissue fragments. Frozen section diagnosis: glioma
in #1 and 2.

B.

SPECIMEN: Left frontal tumor.

HISTOLOGY: None.

GENERAL: Received is a 6 x 6 x 2.2 cm. portion of tan-gray brain
matter admixed with irregular friable pink-tan fibrous
tissue.

SECTIONS: 1X-5X - representative sections submitted.

MICROSCOPIC: A,B. Sections show a high grade glioma with the
following anaplastic features: High cellular density, marked nuclear
pleomorphism fragment, mitotic figures, vascular hyperplasia and
multiple foci of necrosis.TISSUE COMMITTEE CODE:
BILLING CODES

Source: NCI Genomic Data Commons file 639a137e-1591-477c-9922-d71a52419cd4 (TCGA-06-0165.CEE9E681-17BA-493C-BB08-16624A50825C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).